Somatic mutation profile of tumor specimen TCGA-06-2565-01A (aliquot TCGA-06-2565-01A-01D-1494-08) from TCGA case TCGA-06-2565, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.0 years (21,559 days).
Specimen TCGA-06-2565-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d630a395-239a-44cf-bf40-040ed142bbaa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-2565-10A (Blood Derived Normal), aliquot TCGA-06-2565-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/004897bf-5189-4d09-baa3-d45cdde4985a

The open-access MAF lists 55 somatic variants for this specimen: 45 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 9, Frame Shift Del 5, Nonsense Mutation 3, Splice Site 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 3748/3982 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519828, COSV51766433; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.302T>C p.I101T | Missense Mutation (SNP) | VAF 16/92 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1339631701, CD110165, CM110135, CX983284, COSV64289692, COSV64297668, COSV64311547; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMC1A | c.2369G>A p.R790Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs797045993, CM071099, COSV59127614; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS16 | c.1624T>G p.W542G | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV56978507; called by muse, mutect2, varscan2
- ANK1 | c.5428G>A p.V1810M | Missense Mutation (SNP) | VAF 73/166 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.448); catalogued as rs780824103, COSV55873152; called by muse, mutect2, varscan2
- CACNA1S | c.3473C>T p.T1158I | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62936273; called by muse, mutect2, varscan2
- CCT2 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 6/149 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1055658846, COSV54739146; called by muse, mutect2
- CD96 | c.1499C>T p.T500M (on ENST00000283285 / NM_198196.3; = p.T484M on NM_005816.5) | Missense Mutation (SNP) | VAF 94/202 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs140955483; ClinVar: likely benign; called by muse, mutect2, varscan2
- CEACAM20 | c.1676C>A p.P559H | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); catalogued as COSV57600830; called by muse, mutect2, varscan2
- CKB | c.1019A>C p.D340A | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as COSV62379363; called by muse, mutect2, varscan2
- COL6A3 | c.8868del p.A2957Lfs*44 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs398102314; called by mutect2, varscan2*
- COL6A3 | c.8866del p.A2956Lfs*45 | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | catalogued as COSV55095179; called by mutect2, pindel*, varscan2*
- DNA2 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 47/61 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV64427407; called by muse, mutect2, varscan2
- DNMT3L | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs755933301, COSV54263248, COSV54263781; called by muse, mutect2, varscan2
- EGFR | c.1934C>G p.S645C | Missense Mutation (SNP) | VAF 196/5210 reads (4%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); catalogued as rs772046081, COSV51772147; called by muse, mutect2
- FBN2 | c.1411G>A p.V471I | Missense Mutation (SNP) | VAF 81/226 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs138046782, COSV52493545; called by muse, mutect2, varscan2
- FRMD7 | c.1799G>A p.R600H | Missense Mutation (SNP) | VAF 124/145 reads (86%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs751994722, COSV53744666; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GALNT14 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1457685902, COSV61102033; called by muse, mutect2, varscan2
- GCC2 | c.2903A>G p.N968S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs753434393, COSV59174048; called by muse, mutect2, varscan2
- GTSE1 | c.2015T>C p.F672S | Missense Mutation (SNP) | VAF 140/302 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV71888929; called by muse, mutect2, varscan2
- IGHV3-35 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 32/305 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.86); catalogued as rs587745723; called by muse, mutect2
- INPP5J | c.1627G>A p.V543M (on ENST00000331075 / NM_001284285.2; = p.V175M on NM_001002837.2) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs529365616, COSV58511529; called by muse, mutect2, varscan2
- KLF10 | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 89/207 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as COSV53434772; called by muse, mutect2, varscan2
- MAP7D3 | c.2487-1G>A p.X829_splice | Splice Site (SNP) | VAF 114/124 reads (92%) | catalogued as COSV60170061; called by muse, mutect2, varscan2
- NCKAP1L | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 32/734 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs752125351, COSV53203384; called by muse, mutect2
- OBSCN | c.9034G>A p.E3012K | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.089); catalogued as COSV52741204; called by muse, mutect2
- OR56A3 | c.706G>A p.G236S | Missense Mutation (SNP) | VAF 14/379 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.571); catalogued as rs1237266352, COSV61568552; called by muse, mutect2
- PKD2 | c.2329C>T p.Q777* | Nonsense Mutation (SNP) | VAF 80/162 reads (49%) | catalogued as COSV52936542; called by muse, mutect2, varscan2
- PRAMEF14 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 312/735 reads (42%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as rs1465119509, COSV58049541; called by muse, mutect2, varscan2
- RP1 | c.1012C>T p.R338* | Nonsense Mutation (SNP) | VAF 7/111 reads (6%) | catalogued as CM130734, COSV55110264; called by muse, mutect2
- SCN5A | c.2066G>A p.R689H | Missense Mutation (SNP) | VAF 68/169 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs199473145, CM057209; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA3E | c.934del p.V312Ffs*13 | Frame Shift Del (DEL) | VAF 38/103 reads (37%) | catalogued as COSV57080481; called by mutect2, pindel, varscan2
- SFI1 | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs199982480, COSV66291357; called by muse, mutect2, varscan2
- SLCO5A1 | c.1271C>A p.A424E | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52653795; called by muse, mutect2, varscan2
- TCF3 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.475); catalogued as rs748050498, COSV53645657; called by muse, mutect2, varscan2
- TFPT | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 70/239 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.931); catalogued as COSV58084556; called by muse, mutect2, varscan2
- THSD4 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as COSV55961517; called by muse, mutect2, varscan2
- TNK2 | c.1395_1396del p.G466Afs*5 | Frame Shift Del (DEL) | VAF 15/26 reads (58%) | catalogued as COSV57366048; called by mutect2, pindel, varscan2
- TRIM58 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as rs368652011, COSV63569097; called by muse, mutect2, varscan2
- TYW1 | c.593G>A p.W198* | Nonsense Mutation (SNP) | VAF 68/135 reads (50%) | catalogued as COSV62751322; called by muse, mutect2, varscan2
- UHRF1BP1L | c.1160G>C p.G387A | Missense Mutation (SNP) | VAF 76/202 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.146); catalogued as COSV54434621; called by muse, mutect2, varscan2
- ZAP70 | c.1039G>A p.G347S | Missense Mutation (SNP) | VAF 92/177 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1337608513, COSV53852583; called by muse, mutect2, varscan2
- CNTNAP3 | c.3815G>C p.R1272T | Missense Mutation (SNP) | VAF 121/638 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- NUP205 | c.4793+2dup p.X1598_splice | Splice Site (INS) | VAF 55/159 reads (35%) | called by mutect2, pindel, varscan2
- RNF152 | c.25_26del p.L9Afs*129 | Frame Shift Del (DEL) | VAF 50/216 reads (23%) | called by pindel, varscan2
- BMI1 | c.552C>T p.D184= | Silent (SNP) | VAF 65/81 reads (80%) | catalogued as rs777644990, COSV64958698; called by muse, mutect2, varscan2
- CD36 | c.366C>T p.F122= | Silent (SNP) | VAF 62/161 reads (39%) | catalogued as rs761063834, COSV59210382; called by muse, mutect2, varscan2
- DNTTIP1 | c.573C>A p.S191= | Silent (SNP) | VAF 31/117 reads (26%) | catalogued as COSV65459485; called by muse, mutect2, varscan2
- IGHV3-13 | c.153C>T p.Y51= | Silent (SNP) | VAF 78/182 reads (43%) | catalogued as rs782113244; called by muse, varscan2
- LRRC40 | c.1710A>G p.L570= | Silent (SNP) | VAF 43/80 reads (54%) | catalogued as COSV63941591; called by muse, mutect2, varscan2
- NOS1 | c.4206C>T p.V1402= | Silent (SNP) | VAF 246/596 reads (41%) | catalogued as COSV57606930; called by muse, mutect2, varscan2
- PCDHGA1 | c.1734G>A p.A578= | Silent (SNP) | VAF 91/205 reads (44%) | catalogued as rs777400068, COSV65294878; called by muse, mutect2, varscan2
- SLF2 | c.2487A>G p.T829= | Silent (SNP) | VAF 103/129 reads (80%) | catalogued as rs369513139; called by muse, mutect2, varscan2
- UMODL1 | c.2634C>T p.T878= (on ENST00000408910 / NM_001004416.2; = p.T1006= on NM_173568.3) | Silent (SNP) | VAF 163/656 reads (25%) | catalogued as rs757010125, COSV68569279; called by muse, mutect2, varscan2
- CALCR | c.51+2928C>T | Intron (SNP) | VAF 53/99 reads (54%) | catalogued as rs944129546, COSV64006564; called by muse, mutect2, varscan2
